Somatic mutation profile of tumor specimen 0E0AR2 from CCDI case PBCUZT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E0AR2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f446ef7-68c0-43ac-8c54-63806a7ae289.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0ARB (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80d6483a-0b5c-44f1-8da4-93c91521fd88

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Intron 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN3 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 34/358 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1085307995, COSV58823750; ClinVar: likely pathogenic; called by muse, mutect2
- BTN2A2 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 154/488 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.09); catalogued as rs1216152311, COSV61857105, COSV61857765; called by muse, mutect2, varscan2
- TMEM200A | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 77/529 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99032206; called by muse, mutect2, varscan2
- VIPAS39 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs371894407, COSV58939309; ClinVar: uncertain significance; called by muse, mutect2
- GRWD1 | c.1217A>T p.Q406L | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYH13 | c.212C>A p.T71N | Missense Mutation (SNP) | VAF 121/340 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- NOD1 | c.2515C>G p.H839D | Missense Mutation (SNP) | VAF 97/380 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRRS1 | c.21T>C p.T7= | Silent (SNP) | VAF 101/315 reads (32%) | called by muse, mutect2, varscan2
- IGF1R | c.720C>T p.S240= | Silent (SNP) | VAF 42/260 reads (16%) | catalogued as rs745568970; called by muse, mutect2, varscan2
- OR5F1 | c.69A>G p.L23= | Silent (SNP) | VAF 84/255 reads (33%) | called by muse, mutect2, varscan2
- RMDN3 | c.453C>T p.S151= | Silent (SNP) | VAF 35/465 reads (8%) | called by muse, mutect2
- ZDHHC18 | c.1152A>G p.V384= | Silent (SNP) | VAF 107/278 reads (38%) | catalogued as rs1162965189; called by muse, mutect2, varscan2
- ZNF768 | c.1239G>A p.R413= | Silent (SNP) | VAF 31/372 reads (8%) | catalogued as rs766006975, COSV100776038; called by muse, mutect2
- CYP3A5 | c.319-2143C>T | Intron (SNP) | VAF 20/328 reads (6%) | catalogued as rs941060724; called by muse, mutect2
- PIGH | c.-5G>C | 5'UTR (SNP) | VAF 49/110 reads (45%) | called by muse, mutect2
- SPACA9 | chr9:132878118 G>T | 5'Flank (SNP) | VAF 26/86 reads (30%) | called by mutect2, varscan2
